Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A8BV, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A8BV-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

[REDACTED]

....

Clinical Diagnosis & History:

Patient with newly diagnosed retroperitoneal sarcoma.

Specimens Submitted:

- 1: Retroperitoneal sarcoma
- 2: Psoas margin
- 3: Retroperitoneal fat
- 4: Retropsoas margin

DIAGNOSIS:

- 1) SOFT TISSUE, RETROPERITONEAL, EXCISION:
- PLEOMORPHIC MYXOID SARCOMA, HIGH GRADE WITH EXTENSIVE NECROSIS, 14.5 CM GREATEST DIMENSION, INKED MARGINS FREE OF TUMOR (SEE COMMENT).
- 2) PSOAS MARGIN, EXCISION:
- CHRONICALLY INFLAMED SKELETAL MUSCLE AND FIBROADIPOSE TISSUE WITH REACTIVE MYOFIBROBLASTIC PROLIFERATION, NO TUMOR SEEN.
- 3) FAT, RETROPERITONEAL, EXCISION:
- FIBROADIPOSE TISSUE WITH ORGANIZING HEMORRHAGE, CHRONIC INFLAMMATION AND REACTIVE MYOFIBROBLASTIC PROLIFERATION, NO TUMOR SEEN.
- 4) RETROPSOAS MARGIN, EXCISION:
- CHRONICALLY INFLAMED SKELETAL MUSCLE AND FIBROADIPOSE TISSUE WITH REACTIVE MYOFIBROBLASTIC PROLIFERATION, NO TUMOR SEEN.

COMMENT: TUMOR CELLS ARE NEGATIVE FOR CYTOKERATIN (AE1/AE3 AND CAM 5.2), DESMIN, SMA AND MYOGENIN. IN THIS LOCATION DEDIFFERENTIATED LIPOSARCOMA IS POSSIBLE, HOWEVER, HISTOLOGIC SECTIONS DO NOT SHOW RECOGNIZABLE WELL DIFFERENTIATED LIPOSARCOMA. HIGH GRADE MYXOFIBROSARCOMA SHOULD ALSO BE CONSIDERED.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

** Continued on next page **

CSF ICD O-3
Fibromyosarcoma 8811/3
path
Sarcoma, pleomorphic 8802/3
Site: Retroperitoneum C48.0
JW 11/22/13

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 3

Special Studies:

Result	Special Stain	Comment
	AE1:AE3	
	des	
	MYOGENIN	
	SMA	
	CAM 5.2	
	NEG CONT	
	IMM RECUT	

Gross Description:

1) The specimen is received fresh labeled, "Retroperitoneal sarcoma". The specimen consists of a unoriented segment of encapsulated dense fatty tissue measuring 14.5 x 13.5 x 5.5 cm and weighing 1630 grams. The external capsule is inked in black. The specimen is sectioned to reveal multilobulated, fleshy, gelatinous, glistening cut surfaces with diffuse areas of hemorrhage. There are also solid whitish tan areas measuring from 0.3 to 4.5 cm in greatest dimension. Portion of the specimen is been submitted for TPS, electron microscopy and special studies. Representative sections submitted.

Summary of sections:

U-representative section of the variegated cut surface.

2) The specimen is received in formalin and labeled, "PSOAS margin". It consists of two pieces of tan red soft tissue, measuring 3.0 x 1.5 x 0.5 and 3.4 x 1.4 x 0.5 cm. The specimen is not oriented. The entire specimen is submitted.

Summary of section:

M-margin.

3) The specimen is received in formalin and labeled, "Retroperitoneal fat". It consists of an irregular piece of tan yellow lobulated soft tissue, measuring 6 x 4 x 3 cm. Sections show two possible lymph nodes measuring up to 0.2 cm. Representative sections are submitted.

Summary of sections:

LN-lymph nodes?

4) The specimen is received in formalin and labeled, "Retro PSOAS

** Continued on next page **

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

----- Page 3 of 3
margin". It consists of an irregular piece of tan-red membranous soft tissue, measuring 9 x 6 x 1.2 cm. Sections show tan-red surfaces with focal hemorrhagic areas. The surface is inked black. The entire specimen is submitted.

Summary of sections:
M-margin.

Summary of Sections:

Part 1: SP: Retroperitoneal sarcoma

Block	Sect. Site	PCs	
14	u		14

Part 2: SP: Psoas margin

Block	Sect. Site	PCs	
4	m		4

Part 3: SP: Retroperitoneal fat

Block	Sect. Site	PCs	
7	ln		7

Part 4: SP: Retropsoas margin

Block	Sect. Site	PCs	
23	m		23

** End of Report **

Pw TSS - dx discrepancy from status
TCGA tumor to be myxofibrosarcoma.

H/PAA Discrepancy		✓

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____
Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information			
#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Pleomorphic Myxoid Sarcoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Myxofibrosarcoma	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form			
3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The discrepancy is due to differing terminology & use of an alternative terminology rather than a different diagnosis. As the report describes, this is a high grade pleomorphic myxoid sarcoma. Although a dediff Liposarcoma was considered in the differential, no well diff component was identified to confirm this diagnosis. So this tumor is most consistent with Myxofibrosarcoma, high grade.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file c4527608-7d35-47ab-9e18-cc878b59f560 (TCGA-DX-A8BV.D76935FF-D9B4-46F1-B478-6F317AD0A094.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).